Somatic mutation profile of tumor specimen MP2PRT-PAUHRK-TMP1-A (aliquot MP2PRT-PAUHRK-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUHRK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (862 days).
Specimen MP2PRT-PAUHRK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1425a641-61f3-4e07-9f77-9d8106c265c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUHRK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUHRK-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92818d94-5258-4c88-8dbf-f28e805f03fa

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758182700, CM062417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 96/365 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 49/411 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP13A5 | c.2932T>G p.F978V | Missense Mutation (SNP) | VAF 116/413 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60870266; called by muse, mutect2, varscan2
- CREBBP | c.4308T>A p.S1436R | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52128106, COSV99272893; called by muse, mutect2, varscan2
- NCAN | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 253/522 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs778642256; called by muse, mutect2, varscan2
- PACSIN1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 94/470 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1283413633, COSV99762842; called by muse, mutect2, varscan2
- RPS6KA6 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99425481; called by muse, mutect2, varscan2
- RRP1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 65/498 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758930459; called by muse, varscan2
- ST6GAL2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 299/683 reads (44%) | PolyPhen probably damaging (0.932); catalogued as COSV104423633; called by muse, mutect2, varscan2
- CCDC117 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 81/498 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COL4A3 | c.4786C>A p.Q1596K | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB2 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 121/533 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PDZRN4 | c.876T>G p.H292Q (on ENST00000402685 / NM_001164595.2; = p.H34Q on NM_013377.4) | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.34457C>A p.A11486E (on ENST00000591111; = p.A12714E on NM_001267550.2) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | PolyPhen benign (0); called by mutect2, varscan2
- ASTN2 | c.420C>T p.T140= | Silent (SNP) | VAF 54/391 reads (14%) | catalogued as rs753942416, COSV57810640; called by muse, varscan2
- LTBP4 | c.3189C>T p.A1063= (on ENST00000308370 / NM_001042544.1; = p.A1026= on NM_003573.2) | Silent (SNP) | VAF 96/426 reads (23%) | catalogued as rs780903989; called by muse, mutect2, varscan2
- MRGPRX1 | c.783C>T p.S261= | Silent (SNP) | VAF 172/412 reads (42%) | catalogued as rs755616556, COSV57106086; called by muse, mutect2, varscan2
- NFKB2 | c.2538G>T p.L846= | Silent (SNP) | VAF 49/432 reads (11%) | called by muse, mutect2, varscan2
- NRK | c.1698C>T p.A566= | Silent (SNP) | VAF 275/614 reads (45%) | catalogued as rs746356466; called by muse, mutect2, varscan2
- PRL | c.411G>A p.P137= | Silent (SNP) | VAF 50/569 reads (9%) | catalogued as rs371254759, COSV60593288; called by muse, mutect2
- RASAL3 | c.1341C>T p.C447= | Silent (SNP) | VAF 155/525 reads (30%) | catalogued as rs1486220145; called by muse, mutect2, varscan2
- MLIP | c.612+11952C>T | Intron (SNP) | VAF 135/516 reads (26%) | catalogued as rs372263470; called by muse, mutect2, varscan2
